Surgical pathology report (de-identified scan), TCGA case TCGA-76-4925, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Thomas Jefferson University, specimen TCGA-76-4925-01A (Primary Tumor).

[page 1 of 3]
Patient: [REDACTED]

SURGICAL PATHOLOGY REPORT

FINAL DIAGNOSIS:

1. RIGHT FRONTAL BRAIN TUMOR: GLIOBLASTOMA MULTIFORME (WHO GRADE IV), SEE MICROSCOPIC DESCRIPTION.

[REDACTED]
Report Electronically Signed

This diagnostic report has been personally interpreted by the signatory of record.
[REDACTED]

Microscopic Description:

The tumor consists of pleomorphic glial cells. Mitotic figures are present in tumor cells. Tumor necrosis is present. Tumor cells show positive staining on the immunohistochemical stain for glial fibrillary acidic protein (GFAP). The tumor proliferation index as determined by nuclear staining with the immunohistochemical stain Ki67 (MIB-1) is approximately 20%.

Frozen Section Diagnosis:

1. RIGHT FRONTAL BRAIN TUMOR: Glioblastoma multiforme

Clinical History and Diagnosis:

Right frontal brain tumor

[page 2 of 3]
Source of Specimen:

1: RIGHT FRONTAL BRAIN TUMOR

Gross Description:

1. RIGHT FRONTAL BRAIN TUMOR: Received fresh for frozen section are multiple fragments of soft red tissue measuring 0.5 x 0.4 x 0.3cm in aggregate. Touch preps are made. 50% specimen is submitted for frozen section diagnosis. The remaining specimen is submitted for permanent sections.

Histology Laboratory

H&E

Part 1: RIGHT FRONTAL BRAIN TUMOR

UNSTAINED

[page 3 of 3]
[REDACTED]

Patient: [REDACTED]

IMMUNOPATHOLOGY REPORT

EVALUATION:

GFAP: POSITIVE STAINING IN TUMOR CELLS

KI67: POSITIVE STAINING IN APPROXIMATELY 20% OF TUMOR CELL NUCLEI

Comment:

The immunohistochemical stains support the diagnosis of glioblastoma multiforme. See corresponding surgical pathology report [REDACTED]

[REDACTED]

Report Electronically Signed

This diagnostic report has been personally interpreted by the signatory of record.

[REDACTED]

Source: NCI Genomic Data Commons file 4dd01474-f94d-4b86-b202-2e80f32eecda (TCGA-76-4925.886C961A-CFEF-4F2C-8B58-7708E216DB0E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).